Somatic mutation profile of tumor specimen TCGA-27-1833-01A (aliquot TCGA-27-1833-01A-01D-1494-08) from TCGA case TCGA-27-1833, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.3 years (24,592 days).
Specimen TCGA-27-1833-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a29f2cf-7817-4141-9592-6bc1789d43d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1833-10A (Blood Derived Normal), aliquot TCGA-27-1833-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/660ecea7-71bd-41af-9004-98a2a14785c6

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs148254279, COSV51026711; called by muse, mutect2, varscan2
- BRWD3 | c.4252C>T p.R1418* | Nonsense Mutation (SNP) | VAF 116/211 reads (55%) | catalogued as COSV64744675; called by muse, mutect2, varscan2
- CACNA1H | c.2556C>A p.Y852* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV61985685; called by muse, mutect2, varscan2
- CD33 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs748041775, COSV51800414; called by muse, mutect2, varscan2
- CNTN6 | c.2152G>A p.V718I | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs140014929, COSV63183796; called by muse, mutect2, varscan2
- CPS1 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs148519116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP8B1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.315); catalogued as COSV60225647; called by muse, mutect2, varscan2
- DCHS1 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.919); catalogued as rs774036164, COSV55031952, COSV55046006; called by muse, mutect2, varscan2
- DNAH9 | c.7586G>A p.G2529D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377663702; called by muse, mutect2, varscan2
- EPHA10 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs761133986, COSV57621826; called by muse, mutect2, varscan2
- FCGBP | c.9388G>A p.A3130T | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs367948062; called by muse, varscan2
- GPR4 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.28); catalogued as COSV59916365; called by muse, mutect2, varscan2
- IGF2BP1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs779507141, COSV51729787; called by muse, mutect2, varscan2
- IGHD | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101162905; called by muse, mutect2
- IGKV5-2 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1248614829; called by muse, mutect2
- IL4R | c.363G>A p.V121= | Splice Region (SNP) | VAF 25/82 reads (30%) | catalogued as COSV50139062; called by muse, mutect2, varscan2
- ILDR2 | c.834T>A p.H278Q | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV54829481; called by muse, mutect2, varscan2
- KIR3DL3 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 154/564 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99399958; called by muse, mutect2, varscan2
- KMT2C | c.7099A>G p.T2367A | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.185); catalogued as COSV51399339; called by muse, mutect2, varscan2
- KRT19 | c.894C>A p.D298E | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as COSV54178368; called by muse, mutect2, varscan2
- LRRIQ3 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 66/180 reads (37%) | catalogued as rs753314061, COSV63041846; called by muse, mutect2, varscan2
- MAGEB4 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV64396811; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.447); catalogued as rs746610938, COSV51717466; called by muse, mutect2, varscan2
- MEF2A | c.722G>A p.G241D (on ENST00000557942 / NM_001319206.2; = p.G243D on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.732); catalogued as rs967480004, COSV57530732; called by muse, mutect2, varscan2
- NXF1 | c.1759A>G p.K587E | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53672674; called by muse, mutect2, varscan2
- NXF3 | c.1053G>A p.Q351= | Splice Region (SNP) | VAF 124/270 reads (46%) | catalogued as COSV67702910; called by muse, mutect2, varscan2
- OGDHL | c.2920C>T p.R974W | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534879619, COSV65101423; called by muse, mutect2, varscan2
- OR4C6 | c.125T>A p.L42H | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV58602849, COSV58605633; called by muse, mutect2, varscan2
- PON1 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55930970; called by muse, mutect2, varscan2
- RARB | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.019); catalogued as rs1399226180; called by muse, mutect2
- RIPK4 | c.1978G>A p.A660T (on ENST00000352483; = p.A612T on NM_020639.3) | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371705604, COSV60186127; called by muse, mutect2, varscan2
- SACS | c.9227C>A p.T3076N | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66536037; called by muse, mutect2, varscan2
- SCNN1G | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 145/323 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as rs752038199, COSV55597592, COSV55599455; called by muse, mutect2, varscan2
- SEMG2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as rs770342441, COSV65647285; called by muse, mutect2, varscan2
- SERPINB2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs922692149, COSV55091465; called by muse, mutect2, varscan2
- SHANK3 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1364369766, COSV53184490; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2011C>T p.R671* (on ENST00000540229 / NM_001371097.1; = p.R610* on NM_001009562.4) | Nonsense Mutation (SNP) | VAF 118/323 reads (37%) | catalogued as rs1426459557, COSV67441338; called by muse, mutect2, varscan2
- SOX9 | c.250T>G p.Y84D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55422374; called by muse, mutect2, varscan2
- SPTB | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767566180, COSV101072325, COSV67630315; called by muse, mutect2, varscan2
- SULF2 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760782481, COSV63414590; called by muse, mutect2, varscan2
- TRAF3IP2 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60675227; called by muse, mutect2, varscan2
- TRBV4-1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 126/430 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs757587458; called by muse, varscan2
- WDR72 | c.1652T>A p.L551Q | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV64742664; called by muse, mutect2, varscan2
- B3GNT8 | c.618_619del p.Y206* | Nonsense Mutation (DEL) | VAF 32/130 reads (25%) | called by mutect2, pindel, varscan2
- PAM | c.2562_2563del p.K855Tfs*44 (on ENST00000438793 / NM_001319943.1; = p.K855Tfs*45 on NM_000919.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 67/193 reads (35%) | called by mutect2, pindel, varscan2
- TRRAP | c.8848_8854del p.N2950Afs*16 (on ENST00000359863 / NM_001244580.1; = p.N2932Afs*16 on NM_003496.3) | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | called by mutect2, pindel, varscan2
- A4GALT | c.528C>T p.D176= | Silent (SNP) | VAF 83/174 reads (48%) | catalogued as COSV50744107; called by muse, mutect2, varscan2
- CACNA1A | c.2436G>A p.T812= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV64192182; called by muse, mutect2, varscan2
- CNNM1 | c.2427C>T p.D809= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as rs532479735, COSV63200777; called by muse, mutect2, varscan2
- D2HGDH | c.621C>T p.N207= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs766755320, COSV58319410; called by muse, mutect2, varscan2
- EPB41L3 | c.2301C>T p.A767= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as rs774095567, COSV59446952; called by muse, mutect2, varscan2
- GPR4 | c.300T>C p.N100= | Silent (SNP) | VAF 65/271 reads (24%) | catalogued as COSV59916370; called by muse, mutect2, varscan2
- MPP7 | c.1491A>G p.T497= | Silent (SNP) | VAF 43/208 reads (21%) | catalogued as rs1338420194, COSV61730654; called by muse, mutect2, varscan2
- MROH5 | c.2400C>T p.H800= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs1362333726, COSV71300675; called by muse, mutect2, varscan2
- NCL | c.387C>A p.I129= | Silent (SNP) | VAF 44/226 reads (19%) | catalogued as COSV59545191; called by muse, mutect2
- NSD2 | c.2196A>G p.V732= | Silent (SNP) | VAF 159/379 reads (42%) | catalogued as COSV56387684; called by muse, mutect2, varscan2
- PIK3CG | c.2190C>T p.H730= | Silent (SNP) | VAF 86/233 reads (37%) | catalogued as rs756127057, COSV63246532; called by muse, mutect2, varscan2
- PKHD1 | c.11007G>A p.S3669= | Silent (SNP) | VAF 26/235 reads (11%) | catalogued as rs142855690; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- POLE | c.4788G>A p.L1596= | Silent (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2
- SH3BP4 | c.1350C>T p.Y450= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs201095699; called by muse, mutect2, varscan2
- STAC3 | c.258C>T p.N86= | Silent (SNP) | VAF 47/163 reads (29%) | catalogued as rs148939626; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMPRSS15 | c.318T>C p.Y106= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs1218966112, COSV53036125; called by muse, mutect2, varscan2
- ZFP64 | c.63G>A p.T21= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs529661940, COSV53797132; called by muse, mutect2
